Gene-level copy-number profile of tumor specimen TCGA-VQ-AA6I-01A from TCGA case TCGA-VQ-AA6I, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 68.7 years (25,091 days).
Specimen TCGA-VQ-AA6I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.2fe4a60b-7a93-4cbf-a2cd-9f785c10c545.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-AA6I-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1c4caf3f-97d6-4c8b-a87b-63973279dc86

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 796; copy number 2: 19,600; copy number 3: 26,948; copy number 4: 10,445; copy number 5: 566; copy number 6: 561; copy number 7: 115; copy number 8: 42; copy number 9: 190; copy number 10: 111; copy number 11: 57; copy number 12: 22; copy number 13: 5; copy number 14: 60; copy number 15: 53; copy number 16: 15; copy number 18: 15; copy number 20: 10; copy number 21: 33; copy number 23: 3; copy number 26: 54; copy number 30: 22; copy number 31: 23; copy number 43: 28; copy number 47: 8; copy number 49: 8; copy number 50: 7; copy number 52: 15; copy number 60: 3; copy number 68: 1; copy number 71: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-AA6I-01A-11D-A40Z-01): tumor purity 0.46, ploidy 2.95, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 902 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:94,725,674–98,398,601, 143 genes, copy number 10–26 (broad region; genes not listed).
- chr4:57,720,035–59,046,959, 9 genes, copy number 10 (within-gene range 4–10): AC093725.1, AC104790.1, SRIP1, AC096725.1, LINC02494, AC019133.1, AC017091.1, LINC02619, LINC02429.
- chr5:659,862–1,933,985, 49 genes, copy number 9–15 (within-gene range 2–15): TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, AC026748.7, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, AC026412.4, MIR4277, AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3.
- chr5:1,963,346–1,969,013, 2 genes, copy number 15: AC126768.1, AC126768.2.
- chr5:4,012,708–4,041,764, 2 genes, copy number 8: AC025773.1, AC025187.1.
- chr5:4,640,731–4,648,254, 1 gene, copy number 16: AC010634.1.
- chr5:18,958,147–20,575,873, 9 genes, copy number 10–14 (within-gene range 6–14): Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15, CDH18, AC093303.1, AC094103.1, CDH18-AS1.
- chr5:20,967,211–23,689,386, 23 genes, copy number 8–23: AC140168.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1.
- chr5:24,729,379–25,445,925, 16 genes, copy number 7: AC091893.2, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2.
- chr5:28,213,359–29,949,130, 23 genes, copy number 8–20: AC093300.1, LINC02103, AC008825.1, AC109472.1, RNU6-909P, AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4, AC024589.2, AC024589.1, AC024589.3, AC112172.2, LINC02064, AC027345.1, UBL5P1, AC108082.1, AC010374.2, AC010374.1, RN7SKP207.
- chr5:30,733,557–31,267,610, 4 genes, copy number 9 (within-gene range 6–9): AC026433.1, RPL19P11, AC026421.1, AC113386.1.
- chr5:34,837,549–41,587,787, 111 genes, copy number 8–18 (broad region; genes not listed).
- chr7:52,493,152–56,448,375, 85 genes, copy number 7–50 (broad region; genes not listed).
- chr7:89,443,946–94,834,447, 89 genes, copy number 9–71 (within-gene range 4–71) (broad region; genes not listed).
- chr7:104,126,341–105,013,044, 9 genes, copy number 49–68 (within-gene range 3–68): ORC5, LHFPL3, EIF4BP6, LHFPL3-AS1, AC091286.1, LHFPL3-AS2, RN7SL8P, AC007384.1, LINC01004.
- chr7:105,819,492–106,770,207, 14 genes, copy number 52: AC005099.1, CDHR3, AC004836.1, SYPL1, DCAF13P1, RNU6-392P, NAMPT, AC007032.1, LARP1BP2, AC004917.1, AC005050.3, AC005050.1, AC005050.2, CCDC71L.
- chr7:106,781,600–106,781,715, 1 gene, copy number 52: RNA5SP236.
- chr7:109,322,320–109,660,802, 3 genes, copy number 60: AC002386.1, AC073071.1, AC073387.1.
- chr8:5,072,645–5,854,977, 12 genes, copy number 14–18: AC019176.1, AC019176.2, SNORA70, RN7SL318P, AC007718.1, AC091193.1, RPL23AP54, AC004944.1, AC084768.1, AC084768.2, AC087369.1, AC087369.2.
- chr8:6,403,551–6,980,080, 23 genes, copy number 31: AC016065.1, MCPH1, AC016065.2, ANGPT2, AC018398.2, AF287957.1, MCPH1-AS1, MIR8055, AGPAT5, MIR4659A, MIR4659B, AF233439.2, XKR5, GS1-24F4.2, DEFB1, RPL23AP96, DEFA6, AF233439.1, DEFA4, DEFA8P, DEFA9P, DEFA10P, DEFA1.
- chr8:8,555,738–11,790,386, 91 genes, copy number 21–47 (broad region; genes not listed).
- chr19:55,708,438–57,438,457, 89 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr19:57,571,566–58,605,223, 94 genes, copy number 9–14 (within-gene range 4–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 758. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
